FM case AD17383 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Germ Cell Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/934670d9-127e-486f-bbdb-39a68bf222ca

Female, 19.0 years: Germ cell tumor, NOS (ICD-O-3 9064/3) of the ovary; metastasis biopsied or resected from the specified parts of peritoneum. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
